Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1E0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1E0-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Adenocarcinoma, endometrioid, NOS 8380/3
Site Code: Endometrium C54.1

TSS Name/##:

1/1:

f

Specimens Submitted:

- 1: SP: Right paraaortic lymph nodes
- 2: SP: Uterus, cervix, fallopian tubes and ovaries; total hysterectomy and bilateral salpingo-oophorectomy
- 3: SP: Right external iliac sentinel lymph node
- 4: SP: Left external iliac sentinel lymph node
- 5: SP: Subaortic lymph nodes
- 6: SP: Left paraaortic lymph nodes
- 7: SP: Left uterosacral nodule
- 8: SP: Rectoserosal nodule
- 9: SP: Rectoserosa nodule #2

DIAGNOSIS:

1. SP: Right para-aortic lymph nodes; dissection:
- Metastatic adenocarcinoma in one of four lymph nodes (1/4).
2. SP: Uterus, cervix, fallopian tubes and ovaries; total hysterectomy and bilateral salpingo-oophorectomy:
Tumor Type:
Adenocarcinoma, endometrioid type
Architectural Grade (For Endometrioid Types only):
II (6-50% solid growth)
Nuclear Grade (For Endometrioid Types only):
Grade 2
FIGO Grade (For Endometrioid Types only):
Grade 2
Myometrial Invasion:
($\leq 50\%$)
Measures 9mm in maximum depth
Myometrium thickness measures 26mm in the area of maximal tumor invasion
Endocervical Invasion:
Not identified
Lymphovascular invasion:
Identified
Endometrium:

** Continued on next page **

Reviewed: 1/12/11

[page 2 of 3]
TSS Name/##:

Page 2 of 7

Exhibits complex hyperplasia with atypia

Myometrium:

Exhibits multiple leiomyomata

Adnexa:

Benign ovaries and fallopian tubes

3. SP: Sentinel lymph node, right external iliac; excision:
- Two benign lymph nodes (0/2).
- Deeper level recuts and special stains have been ordered. The results will be reported in an addendum.
4. SP: Sentinel lymph node, left external iliac; excision:
- One benign lymph node (0/1).
- Deeper level recuts and special stains have been ordered. The results will be reported in an addendum.
5. SP: Subaortic lymph nodes; excision:
- One benign lymph node (0/1).
6. SP: Left para-aortic lymph nodes; excision:
- Four benign lymph nodes (0/4).
7. SP: Left uterosacral nodule; excision:
- Metastatic adenocarcinoma.
8. SP: Rectoserosal nodule; excision:
- Metastatic adenocarcinoma.
9. SP: Rectoserosal nodule #2; excision:
- Benign fibroadipose tissue with focal calcification.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 3]
TSS Name/#:

Page 6 of 7

Procedures/Addenda:
Addendum

Addendum Diagnosis

PARTS 3, 4

SITE: SENTINEL LYMPH NODES, RIGHT AND LEFT EXTERNAL ILIAC:

- Additional H/E stained sections and immunohistochemical stains for cytokeratins (AE1:AE3) show no evidence of metastatic tumor.

Addendum

Addendum Diagnosis

Part 2

Site: Uterus

- Results of immunohistochemical staining for DNA mismatch repair proteins are as follows:

- MLH1: staining present in tumor.
- PMS2: staining present in tumor.
- MSH2: staining present in tumor.
- MSH6: staining present in tumor.

Conclusion:

Immunohistochemical staining for the tested DNA mismatch repair proteins is retained in the tumor.

Source: NCI Genomic Data Commons file 8646f70f-172a-40ac-811b-4e6174a86dd4 (TCGA-AP-A1E0.700FD29A-69DC-4B34-B841-FFFA7E76A5AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).